Gene-level copy-number profile of tumor specimen TCGA-BB-7862-01A from TCGA case TCGA-BB-7862, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 68.0 years (24,823 days).
Specimen TCGA-BB-7862-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.02cd37d3-965c-4d84-bc60-ee8dc791caa2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-7862-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/74d91789-9860-491f-9f98-0e197f5e2bb0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 18,849; copy number 2: 36,130; copy number 3: 3,660; copy number 4: 986; copy number 5: 182.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BB-7862-01): tumor purity 0.8, ploidy 1.83, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes: Y_RNA, RNU6-904P, RPS16P3.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 182 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,095,150–43,544,057, 169 genes, copy number 5 (broad region; genes not listed).
- chr18:25,818,234–26,438,041, 13 genes, copy number 5 (within-gene range 3–5): RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543.

Autosomal genes at a single copy (total copy number 1): 16,434. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
